Gene-level copy-number profile of tumor specimen TCGA-24-0966-01A from TCGA case TCGA-24-0966, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 78.1 years (28,529 days).
Specimen TCGA-24-0966-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9d3f40aa-e8d4-4031-b41b-6ccb637a8b66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-0966-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9f3fa38a-1b92-46ee-bf64-d4a4aef96644

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,982; copy number 2: 44,075; copy number 3: 2,526; copy number 4: 507; copy number 5: 592; copy number 6: 37; copy number 7: 88; copy number 9: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-0966-01): tumor purity 0.95, ploidy 1.93, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 729 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:21,242,242–21,525,417, 1 gene, copy number 7 (within-gene range 2–7): GREB1L.
- chr18:21,380,286–25,056,760, 87 genes, copy number 7 (broad region; genes not listed).
- chr18:25,818,234–27,795,637, 36 genes, copy number 6: RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1.
- chr18:28,638,714–29,361,963, 6 genes, copy number 5: AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1.
- chr18:38,655,209–38,688,033, 1 gene, copy number 6: AC100781.1.
- chr18:42,052,705–43,129,039, 8 genes, copy number 5: AC087683.2, AC087683.1, AC087683.3, LINC00907, RNA5SP454, AC084335.1, RIT2, AC100779.1.
- chr18:43,499,173–45,683,688, 17 genes, copy number 5–9 (within-gene range 4–9): AC022743.1, AC083760.1, RNA5SP455, AC110014.1, LINC01478, KRT8P5, MLECP1, SETBP1-DT, SETBP1, AC021766.1, MIR4319, AC105074.1, AC090376.1, SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3.
- chr19:15,235,519–23,512,656, 433 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:27,638,483–34,229,515, 140 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,982. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
